Gene-level copy-number profile of tumor specimen TCGA-BK-A26L-01A from TCGA case TCGA-BK-A26L, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 71.2 years (26,002 days).
Specimen TCGA-BK-A26L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.1cf1c682-d68f-459c-ae71-925766e0e9c5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BK-A26L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9e400e87-61ff-4ca1-8344-a7ca1ff3300f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 49; copy number 2: 12,158; copy number 3: 18,562; copy number 4: 21,405; copy number 5: 6,005; copy number 6: 940; copy number 7: 9; copy number 8: 230; copy number 9: 23; copy number 10: 90; copy number 11: 83; copy number 13: 5; copy number 16: 154; copy number 28: 32; copy number 37: 2; copy number 39: 25; copy number 44: 18; copy number 45: 12; copy number 56: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BK-A26L-01A-11D-A275-01): tumor purity 0.57, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 447 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:66,809,993–67,770,468, 23 genes, copy number 9: GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2, MTATP6P21, MTCO3P41, AC005482.1, AC092648.1.
- chr8:40,530,590–43,674,591, 83 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr9:14,475–10,948,481, 154 genes, copy number 16 (broad region; genes not listed).
- chr17:20,290,257–20,595,708, 32 genes, copy number 28: RNU6-1057P, CCDC144CP, RNU6-467P, AC008088.1, Metazoa_SRP, UPF3AP2, USP32P3, SRP68P3, AC015818.9, AC015818.10, NOS2P3, LGALS9B, TNPO1P3, YWHAEP3, KRT16P5, KRT16P3, AC015818.7, KRT17P6, KRT17P7, AC015818.6, AC015818.2, AC015818.5, TBC1D3P3, AC015818.8, AC015818.1, AC015818.3, COTL1P2, AC015818.4, CDRT15L2, ZSWIM5P2, MEIS3P2, AC087499.3.
- chr17:29,625,938–29,930,276, 1 gene, copy number 56 (within-gene range 2–56): SSH2.
- chr17:29,716,279–29,883,109, 7 genes, copy number 56: RPL21P123, AC023389.1, AC023389.2, SNORA70, RPL9P30, AC104982.2, AC104982.1.
- chr17:36,210,924–36,589,848, 18 genes, copy number 44 (within-gene range 2–44): CCL4L2, AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, RNU6-1192P, TBC1D3F, TBC1D3J, ZNHIT3, RNA5SP439, MYO19, PIGW, GGNBP2, AC243732.1.
- chr17:36,861,674–37,056,871, 9 genes, copy number 45 (within-gene range 2–45): LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5.
- chr17:37,140,611–37,163,139, 3 genes, copy number 45: AC244093.1, HMGB1P24, AC244093.2.
- chr17:39,619,613–40,100,589, 27 genes, copy number 37–39: AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1.
- chr18:47,390–3,478,978, 85 genes, copy number 10 (broad region; genes not listed).
- chr18:3,571,215–3,656,282, 5 genes, copy number 10: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1.

Autosomal genes at a single copy (total copy number 1): 49. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
